Somatic mutation profile of tumor specimen MP2PRT-PAVCEP-TMP1-A (aliquot MP2PRT-PAVCEP-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVCEP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,385 days).
Specimen MP2PRT-PAVCEP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c10d2211-7815-4ee4-bc28-a7a2fc53786e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVCEP-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVCEP-NB1-B-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50437120-9311-4000-bbb6-bac9da17cc6e

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 37/160 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1528C>G p.Q510E | Missense Mutation (SNP) | VAF 27/261 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs397507549, CM055503, COSV61004883, COSV61007076; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPER | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs767779708; called by muse, mutect2, varscan2
- CAVIN1 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.054); catalogued as COSV63811426; called by muse, mutect2
- DPYSL4 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 63/388 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs770467261, COSV100061905; called by muse, mutect2, varscan2
- ERG | c.1109A>G p.D370G (on ENST00000398919 / NM_001243428.1; = p.D346G on NM_004449.4) | Missense Mutation (SNP) | VAF 58/664 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55729043; called by muse, mutect2
- NDUFV2 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 77/472 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.445); catalogued as rs777760311; called by muse, mutect2, varscan2
- TEX55 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.236); catalogued as rs755399352, COSV55210681; called by muse, mutect2, varscan2
- TMEM132C | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 61/345 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753914521, COSV100176505, COSV59434327; called by muse, mutect2, varscan2
- TMEM37 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 136/431 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374331367, COSV50027643; called by muse, mutect2, varscan2
- TTN | c.19567G>A p.G6523R (on ENST00000591111; = p.G5596R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/207 reads (28%) | PolyPhen probably damaging (1); catalogued as COSV100630626; called by muse, mutect2, varscan2
- CTNNA3 | c.1979C>A p.A660D | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTTNBP2 | c.4721A>T p.N1574I | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- KIAA1549 | c.3469T>C p.Y1157H | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRGC2 | c.45T>A p.F15L | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CSMD2 | c.2280C>T p.S760= | Silent (SNP) | VAF 70/230 reads (30%) | catalogued as rs145279639; called by muse, mutect2, varscan2
- KIAA1217 | c.603G>A p.P201= | Silent (SNP) | VAF 34/400 reads (9%) | catalogued as rs763164142; called by muse, mutect2
- LYPD8 | c.645C>T p.N215= | Silent (SNP) | VAF 143/332 reads (43%) | catalogued as rs782442637; called by muse, mutect2, varscan2
- NPAS3 | c.111C>T p.D37= | Silent (SNP) | VAF 70/293 reads (24%) | catalogued as rs184013307, COSV58081493; called by muse, mutect2, varscan2
